Gene-level copy-number profile of tumor specimen TCGA-77-6844-01A from TCGA case TCGA-77-6844, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.5 years (27,220 days).
Specimen TCGA-77-6844-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0253cd5d-a580-443d-ab89-b00a5971d025.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-6844-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/468c6ee7-7cbb-4e03-ad0d-59540aba282d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 15,203; copy number 2: 38,132; copy number 3: 5,470; copy number 4: 233; copy number 5: 49; copy number 6: 1; copy number 7: 14; copy number 8: 710; copy number 14: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-6844-01A-11D-1943-01): tumor purity 0.66, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 778 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr7:108,883,975–108,995,029, 4 genes, copy number 14: C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr8:38,225,218–41,578,421, 63 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr16:78,355,529–78,355,834, 1 gene, copy number 6: LSM3P5.

Autosomal genes at a single copy (total copy number 1): 12,820. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
